Somatic mutation profile of tumor specimen TCGA-DD-AACD-01A (aliquot TCGA-DD-AACD-01A-11D-A40R-10) from TCGA case TCGA-DD-AACD, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G4; Age at diagnosis: 48.8 years (17,828 days).
Specimen TCGA-DD-AACD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ea6e1f26-a121-4842-ad60-8656210f212a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-AACD-10A (Blood Derived Normal), aliquot TCGA-DD-AACD-10A-01D-A40U-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8cc4c29a-5495-415f-9cfd-f6657e3b7e85

The open-access MAF lists 94 somatic variants for this specimen: 71 protein-altering or splice-affecting, 22 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 61, Silent 22, Frame Shift Del 2, Frame Shift Ins 2, In Frame Del 2, Splice Site 2, Nonsense Mutation 1, Intron 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.107A>C p.H36P | Missense Mutation (SNP) | VAF 49/166 reads (30%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen possibly damaging (0.498); catalogued as COSV62688989, COSV62691224; called by muse, mutect2, varscan2
- JAK1 | c.2729T>C p.L910P | Missense Mutation (SNP) | VAF 22/72 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61090359; called by muse, mutect2, varscan2
- SMAD4 | c.1156G>A p.G386S | Missense Mutation (SNP) | VAF 39/138 reads (28%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs1057519962, CM147649, COSV61689171, COSV61689611, COSV61697840; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACHE | c.791A>T p.N264I | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99573895; called by muse, mutect2, varscan2
- ADIG | c.32A>G p.D11G | Missense Mutation (SNP) | VAF 26/103 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.275); catalogued as COSV99484907; called by muse, mutect2, varscan2
- AHNAK | c.11270C>T p.P3757L | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs551324364, COSV99946390; called by muse, mutect2, varscan2
- APP | c.890C>A p.T297K | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV100695483, COSV60993827; called by muse, mutect2, varscan2
- ARID2 | c.4502C>T p.S1501F | Missense Mutation (SNP) | VAF 57/180 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.172); catalogued as COSV100535728; called by muse, mutect2, varscan2
- BLM | c.4228C>A p.L1410I | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV61922825; called by muse, mutect2, varscan2
- CALHM2 | c.751T>C p.F251L | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.944); catalogued as rs925694493, COSV99588357; called by muse, mutect2
- CAMTA1 | c.3811A>C p.N1271H | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.135); catalogued as COSV100347667; called by muse, mutect2, varscan2
- CDH23 | c.4949T>G p.L1650R | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.01); catalogued as COSV99819799; called by muse, mutect2, varscan2
- CKM | c.214G>A p.V72M | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.331); catalogued as rs1803285, COSV99675486; called by muse, mutect2, varscan2
- CNTN6 | c.1079C>A p.P360Q | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.295); catalogued as COSV100610401, COSV63171358; called by muse, mutect2, varscan2
- COL17A1 | c.2500C>G p.P834A | Missense Mutation (SNP) | VAF 14/188 reads (7%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.846); catalogued as COSV100793100; called by muse, mutect2
- COL4A4 | c.2336C>A p.P779Q | Missense Mutation (SNP) | VAF 60/175 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.197); catalogued as COSV100306474; called by muse, mutect2, varscan2
- CREB3L3 | c.976-2A>G p.X326_splice | Splice Site (SNP) | VAF 21/74 reads (28%) | catalogued as COSV99313995, COSV99314206; called by muse, mutect2, varscan2
- CRTAC1 | c.299G>A p.R100H | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as rs375692428; called by muse, mutect2, varscan2
- DIDO1 | c.1702C>T p.P568S | Missense Mutation (SNP) | VAF 44/144 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.03); catalogued as COSV56622809, COSV99824642; called by muse, varscan2
- DOCK8 | c.5059G>A p.V1687M | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.528); catalogued as rs767895149, COSV101209866; called by muse, mutect2, varscan2
- DYNC2I1 | c.1601A>T p.Q534L | Missense Mutation (SNP) | VAF 78/180 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.172); catalogued as COSV101337635; called by muse, mutect2, varscan2
- EVC2 | c.1006G>A p.V336I | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT tolerated (0.44); PolyPhen benign (0.012); catalogued as rs761732269, COSV100185420; called by muse, mutect2, varscan2
- FCRL5 | c.1230C>G p.I410M | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100708711; called by muse, mutect2, varscan2
- GOLGA4 | c.6685A>G p.I2229V | Missense Mutation (SNP) | VAF 36/113 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.437); catalogued as COSV62712765; called by muse, mutect2, varscan2
- GRIK4 | c.1973A>T p.D658V | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101483547; called by muse, mutect2, varscan2
- HIKESHI | c.209T>G p.L70R | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1223754309, COSV99563315; called by muse, mutect2, varscan2
- ITGAD | c.363G>C p.K121N | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.88); PolyPhen benign (0.003); catalogued as rs776882400, COSV101210399; called by muse, mutect2, varscan2
- ITPR2 | c.4609A>G p.I1537V | Missense Mutation (SNP) | VAF 35/106 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.021); catalogued as rs1475584874, COSV101189890; called by muse, mutect2, varscan2
- KDM4B | c.1864T>C p.S622P | Missense Mutation (SNP) | VAF 73/240 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.865); catalogued as COSV99345924; called by muse, mutect2, varscan2
- MAN1A2 | c.586A>T p.R196W | Missense Mutation (SNP) | VAF 204/592 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV100740846; called by muse, mutect2, varscan2
- MYPN | c.1936G>A p.V646M | Missense Mutation (SNP) | VAF 17/142 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.105); catalogued as rs772535532, COSV62738919; called by muse, mutect2, varscan2
- NOCT | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 37/141 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0.111); catalogued as COSV99763791; called by muse, mutect2, varscan2
- NOD1 | c.494A>G p.E165G | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV99767920; called by muse, mutect2, varscan2
- NOS1 | c.1285C>G p.L429V | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.668); catalogued as COSV100500278; called by muse, mutect2, varscan2
- OR10G2 | c.377A>C p.D126A | Missense Mutation (SNP) | VAF 76/378 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101606938; called by muse, mutect2
- OR2T6 | c.546del p.T183Pfs*3 | Frame Shift Del (DEL) | VAF 27/135 reads (20%) | catalogued as COSV63216465; called by mutect2, pindel, varscan2
- PCDH18 | c.1111G>A p.E371K | Missense Mutation (SNP) | VAF 73/229 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100787158; called by muse, mutect2, varscan2
- PI4KA | c.5937G>A p.M1979I | Missense Mutation (SNP) | VAF 32/111 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.232); catalogued as COSV99745184; called by muse, mutect2, varscan2
- PIP4K2C | c.1159C>A p.H387N | Missense Mutation (SNP) | VAF 29/112 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); catalogued as COSV100533469; called by muse, mutect2, varscan2
- POLG2 | c.782A>G p.Q261R | Missense Mutation (SNP) | VAF 574/1808 reads (32%) | SIFT tolerated (0.75); PolyPhen benign (0.024); catalogued as COSV73347010; called by muse, mutect2, varscan2
- PRCP | c.1275-1G>A p.X425_splice | Splice Site (SNP) | VAF 15/56 reads (27%) | catalogued as COSV100475772; called by muse, mutect2, varscan2
- PRKCB | c.1859A>T p.K620I | Missense Mutation (SNP) | VAF 34/97 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.143); catalogued as COSV100332975; called by muse, mutect2, varscan2
- RAD54B | c.2489A>T p.E830V | Missense Mutation (SNP) | VAF 200/512 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.035); catalogued as COSV100279574; called by muse, mutect2, varscan2
- REST | c.1978G>A p.G660R | Missense Mutation (SNP) | VAF 34/108 reads (31%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.014); catalogued as COSV100470811; called by muse, mutect2, varscan2
- RGL2 | c.2312A>C p.K771T | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); catalogued as COSV101004740; called by muse, mutect2, varscan2
- RIMS1 | c.305C>A p.A102E | Missense Mutation (SNP) | VAF 60/113 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.424); catalogued as COSV53477919, COSV99325333; called by muse, mutect2, varscan2
- SDCCAG8 | c.229C>G p.L77V | Missense Mutation (SNP) | VAF 71/214 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100654020; called by muse, mutect2, varscan2
- SLC35E1 | c.599G>T p.C200F | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.961); catalogued as COSV101290767; called by muse, mutect2, varscan2
- SLC4A11 | c.351A>C p.L117F | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.101); catalogued as COSV101195918; called by muse, mutect2, varscan2
- SPATA20 | c.341A>G p.H114R (on ENST00000356488 / NM_001258372.1; = p.H130R on NM_022827.4) | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99135660; called by muse, mutect2, varscan2
- SRRM1 | c.2588T>C p.V863A | Missense Mutation (SNP) | VAF 64/205 reads (31%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as COSV100104300; called by muse, mutect2, varscan2
- STIP1 | c.878G>A p.R293Q | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.179); catalogued as COSV100534811; called by muse, mutect2, varscan2
- SUSD2 | c.1192C>T p.R398C | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.938); catalogued as rs758581195, COSV64204914; called by muse, mutect2, varscan2
- SYVN1 | c.727T>C p.F243L | Missense Mutation (SNP) | VAF 41/124 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99589019; called by muse, mutect2, varscan2
- TMEM214 | c.1124C>A p.P375H | Missense Mutation (SNP) | VAF 38/117 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV99476142; called by muse, mutect2, varscan2
- TRIM42 | c.966C>A p.D322E | Missense Mutation (SNP) | VAF 39/120 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.223); catalogued as COSV99648159; called by muse, mutect2, varscan2
- TTN | c.13645T>C p.S4549P (on ENST00000591111; = p.S3622P on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/118 reads (29%) | PolyPhen benign (0.271); catalogued as COSV100601653; called by muse, varscan2
- UPF3A | c.420A>G p.K140= | Splice Region (SNP) | VAF 5/48 reads (10%) | catalogued as COSV100677554; called by muse, mutect2, varscan2
- USP22 | c.1273T>G p.Y425D | Missense Mutation (SNP) | VAF 30/214 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.718); catalogued as COSV99820149; called by muse, mutect2, varscan2
- USP9X | c.3820G>A p.G1274S | Missense Mutation (SNP) | VAF 11/231 reads (5%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as COSV100198749; called by muse, mutect2
- WDR33 | c.3577G>T p.E1193* | Nonsense Mutation (SNP) | VAF 26/62 reads (42%) | catalogued as COSV100459755; called by muse, mutect2, varscan2
- ZBED4 | c.1937A>T p.E646V | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as COSV99350988; called by muse, mutect2, varscan2
- ZFAND4 | c.1606A>G p.K536E | Missense Mutation (SNP) | VAF 42/128 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV100762909; called by muse, mutect2, varscan2
- ZNF527 | c.1677T>G p.C559W | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100648710; called by muse, mutect2, varscan2
- ZNF527 | c.1678G>T p.G560W | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100648711; called by muse, mutect2, varscan2
- ACAD10 | c.647_657dup p.E220Qfs*3 | Frame Shift Ins (INS) | VAF 20/106 reads (19%) | called by mutect2, varscan2
- METTL18 | c.1030dup p.R344Kfs*5 | Frame Shift Ins (INS) | VAF 94/345 reads (27%) | called by mutect2, pindel, varscan2
- MPHOSPH10 | c.990_995del p.R330_T332delinsS | In Frame Del (DEL) | VAF 75/285 reads (26%) | called by mutect2, pindel, varscan2
- SCX | c.283T>C p.F95L | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SENP6 | c.1711_1749del p.G571_I583del | In Frame Del (DEL) | VAF 23/230 reads (10%) | called by pindel, varscan2*
- TLCD4 | c.9del p.N4Tfs*23 | Frame Shift Del (DEL) | VAF 24/116 reads (21%) | called by mutect2, pindel, varscan2
- ADAMTS17 | c.3174C>T p.C1058= | Silent (SNP) | VAF 24/75 reads (32%) | catalogued as COSV51487900; called by muse, mutect2, varscan2
- ALDH7A1 | c.480A>G p.L160= | Silent (SNP) | VAF 161/308 reads (52%) | catalogued as COSV101297447; called by muse, mutect2, varscan2
- CCDC17 | c.1233C>T p.S411= | Silent (SNP) | VAF 78/220 reads (35%) | catalogued as rs1285792363, COSV100601702; called by muse, mutect2, varscan2
- COL12A1 | c.132A>G p.S44= | Silent (SNP) | VAF 31/59 reads (53%) | catalogued as rs201454637; ClinVar: likely benign; called by muse, mutect2, varscan2
- CTPS1 | c.87A>G p.S29= | Silent (SNP) | VAF 77/241 reads (32%) | catalogued as COSV101009306; called by muse, mutect2, varscan2
- DLEC1 | c.4482T>C p.S1494= | Silent (SNP) | VAF 26/119 reads (22%) | catalogued as rs928178784, COSV100341773; called by muse, mutect2, varscan2
- DRP2 | c.1876C>T p.L626= | Silent (SNP) | VAF 152/216 reads (70%) | catalogued as COSV100871850; called by muse, mutect2, varscan2
- GPR183 | c.504C>T p.I168= | Silent (SNP) | VAF 25/113 reads (22%) | catalogued as rs763839031, COSV100854173; called by muse, mutect2, varscan2
- IFNG | c.207G>A p.Q69= | Silent (SNP) | VAF 19/76 reads (25%) | catalogued as COSV99971118; called by muse, mutect2, varscan2
- IQSEC1 | c.1821C>A p.A607= | Silent (SNP) | VAF 17/73 reads (23%) | catalogued as COSV99831590; called by muse, mutect2, varscan2
- MINAR1 | c.2451G>A p.L817= | Silent (SNP) | VAF 47/160 reads (29%) | catalogued as COSV100548762; called by muse, mutect2, varscan2
- MYO18A | c.2232G>A p.P744= | Silent (SNP) | VAF 22/63 reads (35%) | catalogued as rs368144764; called by muse, mutect2, varscan2
- RUNDC3A | c.153C>T p.I51= | Silent (SNP) | VAF 14/36 reads (39%) | catalogued as rs775621685, COSV56637959; called by muse, mutect2, varscan2
- SERPINB7 | c.93C>G p.S31= | Silent (SNP) | VAF 26/102 reads (25%) | catalogued as COSV100320562; called by muse, mutect2, varscan2
- SIX2 | c.702C>T p.S234= | Silent (SNP) | VAF 22/74 reads (30%) | catalogued as COSV100284109; called by muse, mutect2, varscan2
- SLC13A4 | c.1515C>G p.T505= | Silent (SNP) | VAF 30/127 reads (24%) | catalogued as COSV100818826; called by muse, mutect2, varscan2
- SNX31 | c.759A>G p.E253= | Silent (SNP) | VAF 52/207 reads (25%) | catalogued as COSV100310024; called by muse, mutect2, varscan2
- SPATA7 | c.609C>G p.P203= | Silent (SNP) | VAF 34/128 reads (27%) | catalogued as COSV99247837; called by muse, mutect2, varscan2
- TPSD1 | c.393G>T p.L131= | Silent (SNP) | VAF 41/321 reads (13%) | catalogued as COSV99273708; called by muse, mutect2, varscan2
- TXNL1 | c.222A>T p.S74= | Silent (SNP) | VAF 20/88 reads (23%) | catalogued as COSV99469518; called by muse, mutect2, varscan2
- WNT10B | c.15C>T p.P5= | Silent (SNP) | VAF 116/370 reads (31%) | catalogued as COSV99975812; called by muse, mutect2, varscan2
- ZNF282 | c.48G>A p.Q16= | Silent (SNP) | VAF 69/142 reads (49%) | catalogued as COSV100021526; called by muse, mutect2, varscan2
- ELMOD1 | c.-86+1032G>C | Intron (SNP) | VAF 18/64 reads (28%) | catalogued as COSV99759768; called by muse, mutect2
